Surgical pathology report (de-identified scan), TCGA case TCGA-5P-A9KA, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University Hospital Erlangen, specimen TCGA-5P-A9KA-01A (Primary Tumor).

Focal Papillary Renal Cell Carcinoma, Type I

Stage: pT1b, pNX, pMX, V0, L0, R1

Grade: GII

ICD-O-Code: 8260/3

Laterality = Right (R)

ICD-O-3
Carcinoma, papillary renal cell
8260/3
Site: (R) Kidney NOS C64.9
5/6/13/14

Source: NCI Genomic Data Commons file 62e4e474-7ab5-4c19-8818-05cfc85cbd0f (TCGA-5P-A9KA.9A0E64A4-CC87-4957-9333-19E1249BFA9C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).